Somatic mutation profile of tumor specimen MMRF_2446_1_BM_CD138pos (aliquot MMRF_2446_1_BM_CD138pos_T1_KHS5U_K15145) from MMRF case MMRF_2446, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.5 years (18,430 days).
Specimen MMRF_2446_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c63dc51e-84b8-455c-a104-ff5e7562c8dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2446_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2446_1_PB_Whole_C2_KHS5U_K15144; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cc22452-15b3-418c-9dd3-1adb8f0359cc

The open-access MAF lists 78 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 16, Silent 14, Intron 10, 5'UTR 3, Nonsense Mutation 1, Splice Site 1, 5'Flank 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ANO2 | c.1602C>G p.N534K (on ENST00000356134 / NM_001278597.3; = p.N538K on NM_001278596.3) | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV59007661; called by muse, mutect2, varscan2
- CAMSAP3 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.489); catalogued as rs780550579; called by muse, mutect2, varscan2
- CRYBG1 | c.4118T>C p.I1373T | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs1162909071; called by muse, mutect2, varscan2
- DSCAML1 | c.2497G>A p.V833I (on ENST00000321322; = p.V773I on NM_020693.4) | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.658); catalogued as rs371097603; called by muse, mutect2, varscan2
- FREM2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs774024998; called by muse, mutect2, varscan2
- IGHV2-70 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs371102764; called by muse, varscan2
- IGHV2-70 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs375225384; called by muse, varscan2
- IGHV2-70 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs548028630; called by muse, varscan2
- IGKV4-1 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs760776890; called by muse, varscan2
- IGKV4-1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs749276071; called by muse, mutect2, varscan2
- IGLV3-1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 138/277 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs372924773; called by muse, varscan2
- IGLV3-1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 138/297 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs61736463; called by muse, varscan2
- MYO5B | c.2833del p.S945Qfs*6 | Frame Shift Del (DEL) | VAF 17/118 reads (14%) | catalogued as rs780982522; called by mutect2, pindel, varscan2
- NT5C1B | c.1189G>A p.V397I (on ENST00000359846 / NM_001199086.2; = p.V337I on NM_033253.4) | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs144184703; called by muse, mutect2, varscan2
- OR6N2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as rs374518057; called by muse, mutect2, varscan2
- PAX3 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.374); catalogued as rs1042051, COSV60585827, COSV60590898; called by muse, mutect2, varscan2
- RBM41 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs775010046; called by muse, mutect2, varscan2
- SNED1 | c.3010+1G>A p.X1004_splice | Splice Site (SNP) | VAF 14/26 reads (54%) | catalogued as rs1471814215; called by muse, mutect2, varscan2
- ZNF283 | c.1492A>G p.S498G | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.258); catalogued as rs769179370; called by muse, mutect2, varscan2
- C6orf132 | c.1814C>A p.A605D | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- DNAJC21 | c.1473T>A p.D491E | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IGLV3-19 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- IGLV3-19 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, varscan2
- MEF2A | c.1465G>A p.D489N (on ENST00000557942 / NM_001319206.2; = p.D483N on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCCB | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZK1IP1 | c.90G>T p.W30C | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKD2 | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLFN12L | c.320T>G p.V107G (on ENST00000260908 / NM_001363830.1; = p.V125G on NM_001195790.1) | Missense Mutation (SNP) | VAF 81/154 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TBPL2 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFF2 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC21A | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- C5 | c.2046G>A p.K682= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- CD207 | c.528C>G p.G176= | Silent (SNP) | VAF 57/108 reads (53%) | catalogued as COSV69652691; called by muse, mutect2, varscan2
- FAXC | c.567G>T p.A189= | Silent (SNP) | VAF 26/56 reads (46%) | called by muse, varscan2
- FCGBP | c.6531G>A p.V2177= | Silent (SNP) | VAF 53/178 reads (30%) | called by muse, mutect2, varscan2
- GABBR1 | c.169C>T p.L57= | Silent (SNP) | VAF 37/204 reads (18%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.342C>T p.Y114= | Silent (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- IGHV2-70 | c.84T>C p.P28= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs377604349; called by muse, varscan2
- IGKV4-1 | c.234T>A p.S78= | Silent (SNP) | VAF 44/50 reads (88%) | catalogued as rs377208814; called by muse, varscan2
- IGLV3-19 | c.271T>C p.L91= | Silent (SNP) | VAF 96/198 reads (48%) | catalogued as rs748465803; called by muse, varscan2
- NRXN3 | c.1833C>T p.G611= (on ENST00000557594 / NM_001272020.2; = p.G1035= on NM_004796.6) | Silent (SNP) | VAF 72/154 reads (47%) | called by muse, mutect2, varscan2
- PRAF2 | c.69G>A p.A23= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as rs1157666682; called by muse, mutect2, varscan2
- SAG | c.969C>T p.T323= | Silent (SNP) | VAF 58/92 reads (63%) | catalogued as rs370127904; called by muse, mutect2, varscan2
- SCUBE2 | c.2134C>T p.L712= (on ENST00000649792 / NM_001367977.2; = p.L557= on NM_001170690.2) | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100496346; called by muse, varscan2
- SOS1 | c.3282T>C p.G1094= | Silent (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- AGBL4 | c.951+18C>T | Intron (SNP) | VAF 17/42 reads (40%) | catalogued as rs191310576; called by muse, mutect2, varscan2
- CCDC69 | c.-120T>C | 5'UTR (SNP) | VAF 116/179 reads (65%) | called by muse, mutect2, varscan2
- DDIT3 | c.-81+1212del | Intron (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- DHCR7 | c.*344T>C | 3'UTR (SNP) | VAF 47/172 reads (27%) | called by muse, mutect2, varscan2
- DIPK2A | c.*2165A>C | 3'UTR (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- DLG5 | c.*1048G>T | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- DNAJC7 | c.406-16T>A | Intron (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- ECT2L | c.179+8441A>G | Intron (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.3300+124del | Intron (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- F13A1 | c.*339G>A | 3'UTR (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- FAM216B | c.*1586T>G | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- FMN1 | c.*5852C>T | 3'UTR (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- GLIS2 | c.*1799C>T | 3'UTR (SNP) | VAF 92/247 reads (37%) | catalogued as rs1245622482; called by muse, mutect2, varscan2
- GNPDA1 | c.-6-374T>A | Intron (SNP) | VAF 62/179 reads (35%) | called by muse, mutect2, varscan2
- HCN1 | c.*2131G>A | 3'UTR (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- ITGAL | c.62-87C>G | Intron (SNP) | VAF 65/140 reads (46%) | called by muse, mutect2, varscan2
- LYSMD3 | c.*2933A>G | 3'UTR (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2, varscan2
- MEGF10 | c.*3556G>C | 3'UTR (SNP) | VAF 75/138 reads (54%) | called by muse, mutect2, varscan2
- NCAM2 | c.*2301T>G | 3'UTR (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+5054A>G | Intron (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- POLD4 | c.98-100G>C | Intron (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- PPFIA2 | c.303+78770G>A | Intron (SNP) | VAF 131/302 reads (43%) | catalogued as rs1453402392; called by muse, mutect2, varscan2
- RPL32 | c.-357G>C | 5'UTR (SNP) | VAF 71/108 reads (66%) | called by muse, mutect2, varscan2
- SCRN1 | c.*893A>G | 3'UTR (SNP) | VAF 53/116 reads (46%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*4869T>C | 3'UTR (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- SPATA3 | c.-2C>T | 5'UTR (SNP) | VAF 82/164 reads (50%) | called by muse, mutect2, varscan2
- SPATA41 | chr15:100350099 G>A | 5'Flank (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- TIFAB | c.*910G>A | 3'UTR (SNP) | VAF 88/241 reads (37%) | called by muse, mutect2, varscan2
- UBR2 | c.*1121G>T | 3'UTR (SNP) | VAF 51/74 reads (69%) | called by muse, mutect2
- ZFHX4 | c.*2524T>C | 3'UTR (SNP) | VAF 32/60 reads (53%) | catalogued as rs1026428765; called by muse, mutect2, varscan2
- ZNF726 | chr19:23935491 A>C | 3'Flank (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
